Gene-level copy-number profile of tumor specimen TCGA-AA-3549-01A from TCGA case TCGA-AA-3549, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 69.6 years (25,415 days).
Specimen TCGA-AA-3549-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.8d8c92f6-0aac-4f3c-b8f0-44ea77b9a9d4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3549-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c8ce525-1f35-4007-82e9-7798b3e9bb41

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 9,522; copy number 2: 47,283; copy number 3: 93; copy number 4: 1,458; copy number 6: 1,391.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3549-01A-02D-0819-01): tumor purity 0.75, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:50,560,087–55,146,645, 51 genes (within-gene range 0–1): MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1, DCC, AC011155.1, VN1R76P, MIR4528, LINC01917, LINC01919, RPL29P32, AC090666.1, MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, CUPIN1P, AC090897.1, AC091135.1, AC091135.2, DYNAP, RAB27B, RPSAP57, AC007673.1, AC098848.1, CCDC68, MAP1LC3P, LINC01929, RNA5SP459.
- chr18:63,871,692–66,604,138, 20 genes: SERPINB2, SERPINB10, HMSD, AC009802.1, SERPINB8, LINC01924, RPL12P39, LINC00305, LINC01538, AC027506.1, AC090348.1, AC007948.1, AC007631.1, LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1, CDH19.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,391 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,522. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
